Gene-level copy-number profile of tumor specimen TCGA-VR-A8EY-01A from TCGA case TCGA-VR-A8EY, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 44.5 years (16,255 days).
Specimen TCGA-VR-A8EY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.6f170450-78d6-41e6-91a0-b35657f2132f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-A8EY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6dec9308-3977-4836-8eb5-2ee9fa90e613

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 4,264; copy number 2: 39,557; copy number 3: 9,756; copy number 4: 3,941; copy number 5: 1,844; copy number 6: 33; copy number 7: 75; copy number 8: 31; copy number 9: 26; copy number 11: 58; copy number 13: 144; copy number 18: 20; copy number 23: 17; copy number 25: 31; copy number 34: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VR-A8EY-01A-11D-A36I-01): tumor purity 0.74, ploidy 2.35, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–409,417, 8 genes: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1.
- chr8:3,373,353–3,426,587, 2 genes: AC026991.1, AC026991.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,290 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:96,536,743–99,490,035, 81 genes, copy number 7–25 (broad region; genes not listed).
- chr2:108,786,757–124,989,325, 264 genes, copy number 5–25 (broad region; genes not listed).
- chr7:53,559,214–62,275,678, 165 genes, copy number 13–34 (broad region; genes not listed).
- chr8:30,578,318–33,045,445, 33 genes, copy number 5: GTF2E2, AC102945.1, SMIM18, RNU5A-3P, GSR, UBXN8, HIKESHIP3, PPP2CB, TEX15, AC090281.1, AC008066.1, PURG, WRN, SUMO2P16, AC009563.1, KCTD9P6, AC068672.2, AC068672.3, AC068672.1, AC090816.1, RNA5SP261, NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1, RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5 (broad region; genes not listed).
- chr13:32,763,438–33,066,143, 5 genes, copy number 5: RNY1P4, AL138820.1, LINC00423, TOMM22P3, KL.
- chr13:33,158,587–33,164,409, 1 gene, copy number 5: STARD13-IT1.
- chr13:33,800,138–36,131,382, 21 genes, copy number 8: AL139081.2, RFC3, RNU5A-4P, AL161891.1, AL160394.2, VDAC1P12, AL160394.1, AL356321.1, LINC02343, LINC00457, AL161716.1, GAMTP2, Metazoa_SRP, AL138690.1, NBEA, SCAND3P1, PHBP13, MAB21L1, AL390071.1, LINC00445, DCLK1.
- chr13:38,533,343–42,992,271, 80 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr13:99,962,964–100,675,093, 18 genes, copy number 5: ZIC5, AL355338.1, ZIC2, LINC00554, NDUFA12P1, PCCA-DT, ASNSP3, PCCA, RPL15P18, AL356575.1, AL353697.1, PCCA-AS1, GGACT, AL356966.1, AL136526.1, RPS26P47, TMTC4, COX5BP6.
- chr13:107,788,342–108,481,817, 10 genes, copy number 8: FAM155A-IT1, AL359436.1, AL136964.1, LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, AL138694.1, HCFC2P1.
- chr13:109,400,696–113,277,734, 78 genes, copy number 6–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,207. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
